Somatic mutation profile of tumor specimen C3N-00293-04 (aliquot CPT0008410009) from CPTAC case C3N-00293, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 73.3 years (26,774 days).
Specimen C3N-00293-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 034e7d35-84d4-4bac-bca5-38b737f2f5c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00293-31 (Blood Derived Normal), aliquot CPT0008430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cac32d98-82bd-4dc5-a0cb-1ff597d14fcd

The open-access MAF lists 400 somatic variants for this specimen: 270 protein-altering or splice-affecting, 85 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 239, Silent 85, Intron 16, RNA 11, Nonsense Mutation 11, Frame Shift Del 11, 3'UTR 8, Splice Site 5, 5'UTR 4, 5'Flank 4, 3'Flank 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 18/163 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 19/464 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCB10 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs1004194310; called by muse, mutect2
- AC005833.1 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated, low confidence (0.7); catalogued as rs144271473, COSV52899683; called by muse, mutect2, varscan2
- AC138647.1 | c.254C>A p.P85Q | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as rs764390129; called by muse, mutect2, varscan2
- ADAR | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 13/429 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1443188796; called by muse, mutect2
- ALX1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1287504419; called by muse, mutect2
- ANXA10 | c.862C>G p.R288G | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.488); catalogued as COSV100829098; called by muse, mutect2
- ASTN2 | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs915263890; called by muse, mutect2
- ATG16L1 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 23/382 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.221); catalogued as rs1405291656; called by muse, mutect2
- BCL9 | c.3848G>C p.R1283T | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV52345168; called by muse, mutect2
- BRINP2 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 20/532 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1215171222, COSV64177199; called by muse, mutect2
- CABYR | c.1058C>A p.S353Y | Missense Mutation (SNP) | VAF 21/484 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs1209996949, COSV59110202; called by muse, mutect2
- CPS1 | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 28/603 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV51828189; called by muse, mutect2
- CRACD | c.2707G>T p.G903C | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.855); catalogued as rs970752158, COSV51716103; called by muse, mutect2
- CSMD1 | c.5290G>C p.V1764L (on ENST00000520002; = p.V1763L on NM_033225.6) | Missense Mutation (SNP) | VAF 64/398 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV59344777; called by muse, mutect2, varscan2
- DCDC1 | c.1634del p.P545Hfs*25 | Frame Shift Del (DEL) | VAF 27/213 reads (13%) | catalogued as COSV100663992; called by mutect2, pindel, varscan2
- DNMT3A | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as rs893934873; called by muse, mutect2
- ESRRG | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV63165308; called by muse, mutect2, varscan2
- FAT4 | c.9005C>T p.T3002M | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1435573726, COSV100627638; called by muse, mutect2
- FCGBP | c.10561G>T p.A3521S | Missense Mutation (SNP) | VAF 35/362 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); catalogued as rs1456744383; called by muse, mutect2
- GEMIN5 | c.1856-1G>C p.X619_splice | Splice Site (SNP) | VAF 8/140 reads (6%) | catalogued as COSV53560844; called by muse, mutect2
- GFRA2 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 50/572 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV60779688; called by muse, mutect2
- GJA4 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.911); catalogued as COSV60725074; called by muse, mutect2
- GON4L | c.6004G>C p.E2002Q | Missense Mutation (SNP) | VAF 29/1008 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.261); catalogued as rs1200555624; called by muse, mutect2
- GYPC | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 25/575 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52146059; called by muse, mutect2
- HMBS | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as rs569520602; called by muse, mutect2, varscan2
- HNRNPDL | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs752417076; called by muse, mutect2, varscan2
- HTR4 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58792548; called by muse, mutect2, varscan2
- IGHV3-43 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as rs752990359; called by muse, mutect2, varscan2
- IL17F | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 40/532 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as COSV104412155; called by muse, mutect2
- IL7R | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 29/466 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV100286319; called by muse, mutect2
- IRF2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255904730, COSV66928316; called by muse, mutect2
- ITGA8 | c.2576T>A p.I859N | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1346081651; called by muse, mutect2
- KCNS1 | c.890C>A p.T297K | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1419101109; called by muse, mutect2
- KCTD1 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58691757; called by muse, mutect2, varscan2
- KCTD8 | c.1079G>C p.C360S | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100760225; called by muse, mutect2
- KDR | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV55771057; called by muse, mutect2
- KIAA0825 | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1300705769; called by muse, mutect2
- LAMB1 | c.2725G>T p.G909W | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55964885, COSV55968412; called by muse, mutect2
- LOXL3 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 10/328 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.175); catalogued as rs1178246345; called by muse, mutect2
- MAGEB6 | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV100983653; called by muse, mutect2, varscan2
- MAP1S | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV100140788; called by muse, mutect2
- MAP3K21 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 68/339 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs770338601; called by muse, mutect2, varscan2
- MED12L | c.2918G>T p.R973L | Missense Mutation (SNP) | VAF 44/383 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV56377885; called by muse, mutect2, varscan2
- MXRA5 | c.4690G>T p.D1564Y | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs774060125; called by muse, mutect2, varscan2
- NF1 | c.4259C>G p.S1420* (on ENST00000358273 / NM_001042492.3; = p.S1399* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 17/339 reads (5%) | catalogued as CM143399, COSV62205621; called by muse, mutect2
- NUBPL | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 16/534 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99809253; called by muse, mutect2
- NVL | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55877474; called by muse, mutect2
- OCEL1 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 77/507 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs201983831, COSV53044831, COSV99285591; called by muse, mutect2, varscan2
- OPRPN | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.53); catalogued as rs753759585, COSV68193637; called by muse, mutect2
- OR14K1 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 38/604 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99315209; called by muse, mutect2
- OR56A3 | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV61569844; called by muse, mutect2, varscan2
- OR5D14 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59455912; called by muse, mutect2
- PCDHB10 | c.1591G>A p.V531M | Missense Mutation (SNP) | VAF 44/884 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV53383019; called by muse, mutect2
- PCLO | c.12439C>T p.H4147Y | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.744); catalogued as COSV61643160; called by muse, mutect2, varscan2
- PGM2L1 | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1369811609; called by muse, mutect2
- PKD1L1 | c.1442A>G p.Y481C | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV56973690; called by muse, varscan2
- PKHD1L1 | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.681); catalogued as COSV65751144; called by muse, mutect2, varscan2
- PWP1 | c.1418G>C p.R473P | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368748715; called by muse, mutect2, varscan2
- RDH12 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 39/824 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1239043055, CM141931; called by muse, mutect2
- RIMS2 | c.1139A>T p.D380V (on ENST00000666250 / NM_001348490.2; = p.D188V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1304643498; called by muse, mutect2
- RNF25 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 14/346 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV55306927; called by muse, mutect2
- SBK2 | c.652G>T p.G218W | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV60014089; called by muse, mutect2
- SCN3A | c.5395A>T p.K1799* | Nonsense Mutation (SNP) | VAF 33/632 reads (5%) | catalogued as rs1170839078; called by muse, mutect2
- SIGLEC14 | c.1145C>A p.T382N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55783821; called by muse, mutect2, varscan2
- SIMC1 | c.844G>T p.D282Y (on ENST00000443967 / NM_001308196.1; = p.D301Y on NM_001308195.2) | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV57902962; called by muse, mutect2, varscan2
- SLC33A1 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443573057; called by muse, varscan2
- SNRPN | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV100577758, COSV57594911; called by muse, varscan2
- SPARC | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV50560163; called by muse, mutect2
- SYNDIG1 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 56/403 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV65232700; called by muse, mutect2, varscan2
- THEMIS | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as rs1220720885; called by muse, mutect2
- TMPRSS15 | c.2360G>A p.G787E | Missense Mutation (SNP) | VAF 65/625 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519182; called by muse, mutect2, varscan2
- TNN | c.2596T>A p.W866R | Missense Mutation (SNP) | VAF 23/462 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53435421; called by muse, mutect2
- TRPS1 | c.1615G>A p.D539N (on ENST00000220888 / NM_001330599.2; = p.D552N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/385 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as COSV104378102; called by muse, mutect2
- TSLP | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as COSV100789197; called by muse, mutect2, varscan2
- WDR72 | c.2934G>T p.W978C | Missense Mutation (SNP) | VAF 28/497 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM097778; called by muse, mutect2
- ZFHX3 | c.3193G>C p.E1065Q | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51724833, COSV51736271; called by muse, mutect2, varscan2
- ZFYVE9 | c.1187C>G p.S396C | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.97); catalogued as COSV55092017; called by muse, mutect2
- ZNF680 | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411115770; called by muse, mutect2
- ABCA13 | c.8947C>A p.H2983N | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- AC090517.4 | c.293A>T p.E98V | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.192); called by muse, mutect2
- ACY3 | c.211C>A p.R71S | Missense Mutation (SNP) | VAF 47/327 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ADAR | c.452G>C p.G151A | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); called by muse, mutect2
- ADCY2 | c.341G>T p.W114L | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ALOX5 | c.646A>T p.S216C | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ALPG | c.397G>C p.A133P | Missense Mutation (SNP) | VAF 36/510 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2
- AMER3 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.792); called by muse, mutect2
- AMIGO1 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD30B | c.2411C>T p.T804I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD52 | c.2639A>T p.H880L | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2
- AOX1 | c.3556G>T p.D1186Y | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARHGAP21 | c.4369G>A p.E1457K | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by mutect2, varscan2
- ARHGAP28 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2
- ARHGAP5 | c.1580G>C p.R527T | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- ARMH4 | c.2146G>T p.V716L | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- ASPM | c.5163G>C p.K1721N | Missense Mutation (SNP) | VAF 35/424 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.482); called by muse, mutect2
- ASTN2 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); called by muse, mutect2
- ATIC | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 21/351 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- ATR | c.6417G>C p.L2139F | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2
- BASP1 | c.280G>C p.A94P | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2
- BCAS1 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 30/451 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- BDP1 | c.3841G>C p.D1281H | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- BRINP1 | c.1906G>T p.G636C | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- BRWD3 | c.5096G>A p.R1699K | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated, low confidence (0.89); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- BTN3A2 | c.219G>T p.R73S | Missense Mutation (SNP) | VAF 58/774 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.946); called by muse, mutect2
- CACNA1D | c.3202G>A p.D1068N (on ENST00000350061 / NM_001128840.3; = p.D1088N on NM_000720.4) | Missense Mutation (SNP) | VAF 20/521 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.009); called by muse, mutect2
- CACTIN | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 33/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- CASP1 | c.786T>G p.F262L (on ENST00000436863 / NM_033292.4; = p.F241L on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/461 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CATIP | c.488T>G p.F163C | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC168 | c.4877A>T p.K1626M | Missense Mutation (SNP) | VAF 37/310 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCDC17 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CCNG1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2
- CCZ1 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP69 | c.2265A>T p.K755N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRNA10 | c.1141G>T p.G381C | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.813); called by muse, mutect2
- CILP2 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL11A1 | c.3215G>A p.G1072D | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL13A1 | c.1764G>T p.K588N (on ENST00000398978 / NM_001130103.2; = p.K516N on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL1A2 | c.927G>T p.K309N | Missense Mutation (SNP) | VAF 90/736 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYP7B1 | c.173T>G p.V58G | Missense Mutation (SNP) | VAF 48/455 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- DACH2 | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DMD | c.5828T>A p.M1943K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DNAI2 | c.1347+6G>T | Splice Region (SNP) | VAF 39/647 reads (6%) | called by muse, mutect2
- DOCK10 | c.4969C>G p.L1657V | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2
- DUOX2 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 32/612 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2
- ELFN1 | c.1366del p.A456Qfs*39 | Frame Shift Del (DEL) | VAF 10/124 reads (8%) | called by mutect2, pindel
- EPHB6 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- EVC2 | c.3318G>T p.L1106F | Missense Mutation (SNP) | VAF 23/563 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- EVC2 | c.2810C>G p.S937C | Missense Mutation (SNP) | VAF 22/640 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2
- FLI1 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FSIP2 | c.9613G>A p.D3205N | Missense Mutation (SNP) | VAF 15/241 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- FSIP2 | c.12931dup p.E4311Gfs*16 | Frame Shift Ins (INS) | VAF 34/252 reads (13%) | called by mutect2, pindel, varscan2
- GAB4 | c.856A>T p.S286C | Missense Mutation (SNP) | VAF 32/638 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- GABRA4 | c.1029C>A p.F343L | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- GJA9 | c.1229C>A p.S410Y | Missense Mutation (SNP) | VAF 22/526 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- GLE1 | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.07); called by muse, mutect2
- GOLGA8O | c.1333A>T p.S445C | Missense Mutation (SNP) | VAF 33/1065 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GP2 | c.553A>T p.T185S (on ENST00000381362 / NM_001007240.3; = p.T182S on NM_001502.4) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.049); called by muse, mutect2
- H4C9 | c.199A>T p.I67F | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); called by muse, mutect2
- HERC2 | c.7917C>G p.I2639M | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HIVEP2 | c.4783G>A p.E1595K | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.056); called by muse, mutect2
- HSD11B1 | c.332-1G>T p.X111_splice | Splice Site (SNP) | VAF 32/867 reads (4%) | called by muse, mutect2
- HYOU1 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.721); called by muse, mutect2
- ICE1 | c.5113G>T p.A1705S | Missense Mutation (SNP) | VAF 45/360 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- IDE | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- IFIT1 | c.1060G>T p.G354C | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- IGBP1P2 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.049); called by muse, mutect2
- IGHJ1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 29/504 reads (6%) | called by muse, mutect2
- IGKV3-15 | c.293T>A p.L98Q | Missense Mutation (SNP) | VAF 90/1346 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- IL10RB | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 56/507 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IL18 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.021); called by muse, mutect2
- INSYN2B | c.589A>G p.K197E | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- IQCC | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ITFG1 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.146); called by muse, mutect2
- JHY | c.1199A>G p.N400S | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- KAZN | c.2271C>A p.S757R | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KCNB2 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.186); called by muse, mutect2
- KCNC2 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.075); called by muse, mutect2
- KDM5C | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 23/376 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2
- KIAA1614 | c.1637C>A p.P546Q | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF7 | c.1784G>T p.G595V | Missense Mutation (SNP) | VAF 54/469 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LMOD2 | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LPCAT4 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.141); called by muse, mutect2
- LRIT1 | c.980T>A p.I327N | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2
- LRRC24 | c.1407G>C p.E469D | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- LRRC3 | c.254A>T p.Q85L | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2
- LVRN | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAN1A1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); called by muse, mutect2
- MAP2K6 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); called by muse, mutect2
- MAP3K19 | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- MEP1B | c.1710C>A p.S570R | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MIB1 | c.2483del p.D828Vfs*66 | Frame Shift Del (DEL) | VAF 22/205 reads (11%) | called by mutect2, pindel, varscan2
- MINDY2 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MMRN1 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- MUC13 | c.1491G>T p.M497I | Missense Mutation (SNP) | VAF 57/508 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYF6 | c.702del p.C235Afs*10 | Frame Shift Del (DEL) | VAF 44/507 reads (9%) | called by mutect2, pindel
- MYH6 | c.3669G>C p.K1223N | Missense Mutation (SNP) | VAF 28/886 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO18B | c.3895G>T p.E1299* | Nonsense Mutation (SNP) | VAF 20/201 reads (10%) | called by muse, mutect2, varscan2
- NCAPD3 | c.1215+2T>C p.X405_splice | Splice Site (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- NDST4 | c.2067C>G p.I689M | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NETO1 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.069); called by muse, mutect2
- NHS | c.4549G>A p.E1517K | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NID2 | c.2610T>A p.H870Q | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NIN | c.3151T>A p.S1051T | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2
- NLRP5 | c.1268del p.S423Ffs*6 | Frame Shift Del (DEL) | VAF 34/271 reads (13%) | called by mutect2, pindel, varscan2
- NME7 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- NOM1 | c.2525G>A p.R842K | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.018); called by muse, mutect2
- NPEPPS | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NRK | c.557C>G p.T186S | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NTRK3 | c.1325C>G p.A442G | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.26); called by muse, mutect2
- NUP58 | c.957G>C p.L319F | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR13C4 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- OR2T1 | c.388A>T p.R130* | Nonsense Mutation (SNP) | VAF 58/297 reads (20%) | called by muse, mutect2, varscan2
- OR4A15 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); called by muse, mutect2
- OR4A15 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- OR4C46 | c.84del p.F30Lfs*50 | Frame Shift Del (DEL) | VAF 24/333 reads (7%) | called by mutect2, pindel
- OR5T1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 23/333 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR8I2 | c.656T>G p.I219S | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8J3 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 23/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OTOA | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 58/575 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- OTOG | c.942G>A p.W314* | Nonsense Mutation (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- OTOGL | c.3837G>T p.R1279S (on ENST00000547103; = p.R1270S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- P2RY13 | c.916del p.A306Qfs*10 | Frame Shift Del (DEL) | VAF 22/194 reads (11%) | called by mutect2, pindel, varscan2
- PALM3 | c.1579G>A p.E527K (on ENST00000340790; = p.E542K on NM_001145028.2) | Missense Mutation (SNP) | VAF 13/341 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2
- PAX6 | c.1190T>C p.I397T | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCDHA1 | c.2219T>A p.V740E | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PCDHGA6 | c.1900G>T p.D634Y | Missense Mutation (SNP) | VAF 64/510 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PIGR | c.1555A>C p.N519H | Missense Mutation (SNP) | VAF 50/589 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2
- PIK3R4 | c.3708+1G>T p.X1236_splice | Splice Site (SNP) | VAF 19/150 reads (13%) | called by muse, mutect2, varscan2
- PIK3R4 | c.3708G>T p.Q1236H | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- PLCL1 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 42/263 reads (16%) | called by muse, mutect2, varscan2
- PPIP5K2 | c.3289+1G>T p.X1097_splice | Splice Site (SNP) | VAF 27/216 reads (13%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.290C>T p.P97L (on ENST00000295902; = p.P41L on NM_198859.4) | Missense Mutation (SNP) | VAF 27/666 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKCG | c.1426A>T p.I476F | Missense Mutation (SNP) | VAF 103/1005 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRKDC | c.4822C>T p.R1608* | Nonsense Mutation (SNP) | VAF 11/223 reads (5%) | called by muse, mutect2
- PRUNE2 | c.8011G>T p.G2671C | Missense Mutation (SNP) | VAF 12/331 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2
- RBM48 | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNASEH1 | c.465G>T p.R155S | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.302); called by muse, mutect2
- RP1L1 | c.4057G>T p.E1353* | Nonsense Mutation (SNP) | VAF 58/1330 reads (4%) | called by muse, mutect2
- RPA4 | c.595A>T p.N199Y | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.29); called by muse, mutect2
- RPS6KA2 | c.385C>A p.Q129K | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2
- RYR2 | c.5462T>A p.L1821H | Missense Mutation (SNP) | VAF 108/626 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SCN4A | c.5270G>C p.S1757T | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.021); called by muse, mutect2
- SEC24A | c.408G>C p.L136F | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.132); called by muse, mutect2
- SELL | c.285C>A p.F95L (on ENST00000650983; = p.F82L on NM_000655.5) | Missense Mutation (SNP) | VAF 26/578 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- SEMA6D | c.1842G>T p.W614C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.428); called by muse, mutect2
- SERAC1 | c.1011_1015del p.S338Lfs*54 | Frame Shift Del (DEL) | VAF 11/121 reads (9%) | called by mutect2, pindel
- SETD1B | c.963C>A p.Y321* | Nonsense Mutation (SNP) | VAF 20/376 reads (5%) | called by muse, mutect2
- SETDB2 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 9/276 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SHANK1 | c.1607del p.G536Afs*27 | Frame Shift Del (DEL) | VAF 17/188 reads (9%) | called by mutect2, pindel
- SIGLEC14 | c.1146C>G p.T382= | Splice Region (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- SLC5A11 | c.1550A>G p.K517R | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- SLC8B1 | c.1745A>G p.K582R | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- SLC9A3R1 | c.522del p.K174Nfs*29 | Frame Shift Del (DEL) | VAF 63/511 reads (12%) | called by mutect2, pindel, varscan2
- SLC9A9 | c.437C>A p.A146E | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLITRK3 | c.144C>A p.C48* | Nonsense Mutation (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- SMCHD1 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SMG5 | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 16/515 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- STAB2 | c.6485T>C p.L2162P | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2
- TARM1 | c.488C>A p.P163H (on ENST00000616041 / NM_001330650.1; = p.P155H on NM_001135686.3) | Missense Mutation (SNP) | VAF 24/463 reads (5%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.947); called by muse, mutect2
- TBXA2R | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TENM1 | c.2365G>A p.G789S | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TENM3 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 22/275 reads (8%) | called by muse, mutect2
- TSC22D3 | c.136A>C p.S46R | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); called by muse, mutect2
- TSGA10 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.27320A>T p.Q9107L (on ENST00000591111; = p.Q8180L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/334 reads (6%) | PolyPhen benign (0.003); called by muse, mutect2
- UACA | c.2688A>T p.E896D | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- UGT2B28 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ULK4 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UPF3A | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- USH2A | c.5720T>A p.L1907Q | Missense Mutation (SNP) | VAF 38/687 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- UTF1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.457); called by muse, mutect2
- VANGL1 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 56/477 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- VAV3 | c.484T>A p.C162S | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.086); called by muse, mutect2
- VEZT | c.2303T>G p.I768R | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.017); called by muse, mutect2
- WBP2NL | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.151); called by muse, mutect2
- WDR3 | c.1808G>C p.G603A | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.334); called by muse, mutect2
- XIRP2 | c.8076G>C p.Q2692H (on ENST00000628543; = p.Q2867H on NM_152381.6) | Missense Mutation (SNP) | VAF 31/356 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.275); called by muse, mutect2
- YY1AP1 | c.1403C>T p.S468F (on ENST00000295566 / NM_139118.2; = p.S411F on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/557 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- ZNF100 | c.146G>T p.W49L | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF35 | c.704C>A p.A235E | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2
- ZNF367 | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF534 | c.1104A>T p.K368N (on ENST00000332323 / NM_001143939.3; = p.K355N on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2
- ZNF578 | c.596G>T p.R199M | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); called by muse, mutect2
- ZNF680 | c.812G>T p.C271F | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF727 | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ZP4 | c.286G>T p.V96F | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZSCAN5B | c.101del p.G34Efs*12 | Frame Shift Del (DEL) | VAF 19/186 reads (10%) | called by mutect2, pindel
- ZSWIM8 | c.4273G>C p.E1425Q (on ENST00000605216 / NM_001242487.2; = p.E1430Q on NM_015037.3) | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2
- AC005833.1 | c.1437G>A p.E479= | Silent (SNP) | VAF 21/183 reads (11%) | called by muse, mutect2, varscan2
- ACOXL | c.309G>T p.G103= | Silent (SNP) | VAF 20/328 reads (6%) | called by muse, mutect2
- ACP4 | c.1182G>T p.L394= | Silent (SNP) | VAF 14/355 reads (4%) | called by muse, mutect2
- ARHGEF10 | c.3645C>T p.I1215= (on ENST00000398564; = p.I1190= on NM_014629.4) | Silent (SNP) | VAF 59/358 reads (16%) | catalogued as rs750357141; called by muse, varscan2
- ASPM | c.7092C>T p.I2364= | Silent (SNP) | VAF 33/326 reads (10%) | catalogued as COSV99661367; called by muse, mutect2, varscan2
- ATP2B2 | c.231G>A p.K77= | Silent (SNP) | VAF 27/232 reads (12%) | catalogued as rs1221907020; called by muse, mutect2, varscan2
- CACHD1 | c.2055C>T p.L685= | Silent (SNP) | VAF 14/308 reads (5%) | called by muse, mutect2
- CCER1 | c.612G>A p.Q204= | Silent (SNP) | VAF 30/411 reads (7%) | called by muse, mutect2
- CDH18 | c.2160G>T p.L720= | Silent (SNP) | VAF 17/476 reads (4%) | catalogued as COSV56916371; called by muse, mutect2
- CMPK2 | c.471A>T p.P157= | Silent (SNP) | VAF 12/197 reads (6%) | called by muse, mutect2
- CRACR2B | c.1137C>T p.C379= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs1194557092; called by muse, mutect2
- CRELD1 | c.18G>T p.P6= | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- CTNND1 | c.1776G>T p.R592= | Silent (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- CYP7B1 | c.174G>T p.V58= | Silent (SNP) | VAF 49/453 reads (11%) | catalogued as COSV100041092, COSV59582350; called by muse, mutect2, varscan2
- DTX3 | c.231A>C p.L77= | Silent (SNP) | VAF 28/265 reads (11%) | called by muse, mutect2, varscan2
- EDIL3 | c.1401C>A p.I467= | Silent (SNP) | VAF 68/706 reads (10%) | catalogued as rs1408988413; called by muse, mutect2
- EEF1B2 | c.9C>T p.F3= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as rs1014902539; called by muse, mutect2
- EPHA4 | c.441C>T p.T147= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as COSV56044490; called by muse, mutect2
- FAM13C | c.288C>T p.F96= | Silent (SNP) | VAF 19/451 reads (4%) | called by muse, mutect2
- FAM47B | c.303G>C p.A101= | Silent (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- FASN | c.4476A>G p.E1492= | Silent (SNP) | VAF 19/405 reads (5%) | called by muse, mutect2
- FAT2 | c.9663C>G p.T3221= | Silent (SNP) | VAF 43/447 reads (10%) | called by muse, mutect2
- FLYWCH1 | c.1143G>A p.L381= (on ENST00000253928 / NM_001308068.2; = p.L380= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/243 reads (8%) | called by muse, mutect2
- FOXD3 | c.1311G>A p.L437= | Silent (SNP) | VAF 25/593 reads (4%) | catalogued as rs1326265755; called by muse, mutect2
- FUT6 | c.456C>T p.F152= | Silent (SNP) | VAF 37/940 reads (4%) | called by muse, mutect2
- G6PC | c.213C>T p.L71= | Silent (SNP) | VAF 62/603 reads (10%) | called by muse, mutect2, varscan2
- GPC5 | c.942C>T p.H314= | Silent (SNP) | VAF 15/161 reads (9%) | catalogued as rs145800702; called by muse, mutect2
- GPR45 | c.534G>A p.R178= | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as rs1204811956; called by muse, mutect2
- GRID1 | c.795G>C p.P265= | Silent (SNP) | VAF 20/186 reads (11%) | called by muse, varscan2
- HES7 | c.124C>A p.R42= | Silent (SNP) | VAF 36/618 reads (6%) | called by muse, mutect2
- HMBS | c.702G>T p.L234= | Silent (SNP) | VAF 47/453 reads (10%) | called by muse, mutect2, varscan2
- JRKL | c.240C>T p.D80= | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- KCNA1 | c.162C>T p.T54= | Silent (SNP) | VAF 30/496 reads (6%) | catalogued as rs1014419258, COSV66838067; called by muse, mutect2
- KIAA0753 | c.2826G>A p.V942= | Silent (SNP) | VAF 14/202 reads (7%) | catalogued as rs1321643887; called by muse, mutect2
- KIF2B | c.582T>C p.Y194= | Silent (SNP) | VAF 40/522 reads (8%) | called by muse, mutect2
- KRTAP7-1 | c.153C>A p.S51= | Silent (SNP) | VAF 22/356 reads (6%) | called by muse, mutect2
- LCORL | c.717C>G p.T239= | Silent (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- LILRB4 | c.1041T>A p.T347= (on ENST00000391733 / NM_001278428.3; = p.T346= on NM_001278426.3) | Silent (SNP) | VAF 25/218 reads (11%) | called by muse, mutect2, varscan2
- LRP5 | c.4764C>T p.D1588= | Silent (SNP) | VAF 35/157 reads (22%) | catalogued as COSV53716492; called by muse, mutect2, varscan2
- LRRC3B | c.153C>T p.S51= | Silent (SNP) | VAF 28/300 reads (9%) | called by muse, mutect2
- MGAM2 | c.1737G>T p.A579= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV72176561; called by muse, mutect2, varscan2
- MIS18BP1 | c.2253G>A p.L751= | Silent (SNP) | VAF 18/327 reads (6%) | called by muse, mutect2
- MYBL1 | c.2169A>G p.T723= | Silent (SNP) | VAF 12/216 reads (6%) | catalogued as rs1220712767; called by muse, mutect2
- MYH11 | c.375C>T p.V125= | Silent (SNP) | VAF 34/664 reads (5%) | called by muse, mutect2
- MYO5A | c.3081G>T p.L1027= | Silent (SNP) | VAF 25/604 reads (4%) | catalogued as COSV62565969; called by muse, mutect2
- MYO5C | c.4314T>C p.F1438= | Silent (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2
- NAALADL2 | c.1266A>T p.T422= | Silent (SNP) | VAF 16/225 reads (7%) | called by muse, mutect2
- NBN | c.2196A>G p.Q732= | Silent (SNP) | VAF 44/302 reads (15%) | catalogued as rs587780780, COSV55375395; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- NPFFR2 | c.1440G>A p.Q480= | Silent (SNP) | VAF 11/257 reads (4%) | called by muse, mutect2
- OCA2 | c.2316G>T p.L772= | Silent (SNP) | VAF 49/574 reads (9%) | called by muse, mutect2
- OR1G1 | c.324G>A p.V108= | Silent (SNP) | VAF 23/300 reads (8%) | called by muse, mutect2
- OR2T27 | c.708G>A p.K236= | Silent (SNP) | VAF 20/368 reads (5%) | called by muse, mutect2
- OR6B1 | c.132C>A p.I44= | Silent (SNP) | VAF 34/296 reads (11%) | called by muse, mutect2, varscan2
- OSBPL10 | c.1482C>G p.P494= | Silent (SNP) | VAF 58/447 reads (13%) | catalogued as rs745630229; called by muse, mutect2, varscan2
- PAK6 | c.516G>A p.G172= | Silent (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- PIEZO2 | c.6558G>T p.V2186= | Silent (SNP) | VAF 15/290 reads (5%) | called by muse, mutect2
- PIGR | c.1554G>T p.V518= | Silent (SNP) | VAF 50/586 reads (9%) | called by muse, mutect2
- PIK3R2 | c.156G>A p.Q52= | Silent (SNP) | VAF 30/246 reads (12%) | catalogued as COSV53217400; called by muse, mutect2, varscan2
- PLAG1 | c.870C>T p.L290= | Silent (SNP) | VAF 18/392 reads (5%) | called by muse, mutect2
- PLSCR2 | c.138G>A p.Q46= | Silent (SNP) | VAF 10/335 reads (3%) | catalogued as COSV100367781; called by muse, mutect2
- PRR23B | c.411C>T p.V137= | Silent (SNP) | VAF 43/407 reads (11%) | called by muse, mutect2, varscan2
- RASA2 | c.1548C>T p.A516= | Silent (SNP) | VAF 22/339 reads (6%) | catalogued as rs765379914, COSV53940818, COSV53942434; called by muse, mutect2
- RASGRP1 | c.2274G>A p.L758= | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- RNF207 | c.1218C>T p.I406= | Silent (SNP) | VAF 11/242 reads (5%) | called by muse, mutect2
- RNF31 | c.2793C>G p.L931= | Silent (SNP) | VAF 22/274 reads (8%) | catalogued as COSV60729649; called by muse, mutect2
- RXFP2 | c.1416C>T p.G472= | Silent (SNP) | VAF 31/332 reads (9%) | called by muse, mutect2
- SEC31A | c.3156C>T p.F1052= (on ENST00000355196 / NM_001318120.1; = p.F1013= on NM_016211.4) | Silent (SNP) | VAF 17/576 reads (3%) | catalogued as COSV52341378; called by muse, mutect2
- SERPINB11 | c.1065T>A p.A355= | Silent (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- SLC10A2 | c.201C>A p.G67= | Silent (SNP) | VAF 23/215 reads (11%) | catalogued as COSV55361805; called by muse, mutect2, varscan2
- SLC13A5 | c.483C>A p.A161= | Silent (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- SLC36A2 | c.423T>C p.N141= | Silent (SNP) | VAF 29/468 reads (6%) | called by muse, mutect2
- SLC4A10 | c.1941C>G p.L647= (on ENST00000446997 / NM_001354461.2; = p.L617= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2, varscan2
- SLC4A4 | c.1362G>A p.A454= (on ENST00000264485 / NM_001098484.3; = p.A410= on NM_003759.4) | Silent (SNP) | VAF 20/305 reads (7%) | catalogued as rs754788772, COSV52623410; called by muse, mutect2
- SPEG | c.6930C>T p.P2310= | Silent (SNP) | VAF 44/567 reads (8%) | called by muse, mutect2
- SPTA1 | c.4693C>T p.L1565= | Silent (SNP) | VAF 21/684 reads (3%) | catalogued as COSV63757353; called by muse, mutect2
- TACR1 | c.201G>A p.T67= | Silent (SNP) | VAF 22/332 reads (7%) | catalogued as COSV59479068; called by muse, mutect2
- TARBP2 | c.198C>T p.V66= (on ENST00000266987 / NM_134323.2; = p.V45= on NM_004178.4) | Silent (SNP) | VAF 18/264 reads (7%) | catalogued as COSV57200768; called by muse, mutect2
- THSD7A | c.1168C>A p.R390= | Silent (SNP) | VAF 27/579 reads (5%) | catalogued as COSV70260426; called by muse, mutect2
- TMEM74B | c.591C>T p.V197= | Silent (SNP) | VAF 21/161 reads (13%) | called by muse, mutect2, varscan2
- TRIM71 | c.2196C>T p.V732= | Silent (SNP) | VAF 16/422 reads (4%) | called by muse, mutect2
- TTC28 | c.5178G>A p.Q1726= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- UBN2 | c.2040G>C p.V680= | Silent (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- USH2A | c.6975A>T p.L2325= | Silent (SNP) | VAF 13/368 reads (4%) | called by muse, mutect2
- ZFHX3 | c.3309C>T p.L1103= | Silent (SNP) | VAF 26/426 reads (6%) | called by muse, mutect2
- ZNF429 | c.1266G>A p.E422= | Silent (SNP) | VAF 20/219 reads (9%) | catalogued as COSV61916896; called by muse, mutect2
- AC025048.6 | n.690G>C | RNA (SNP) | VAF 18/354 reads (5%) | called by muse, mutect2
- AC068633.1 | n.227G>C | RNA (SNP) | VAF 28/215 reads (13%) | called by muse, mutect2, varscan2
- AC114490.3 | c.*158T>C | 3'UTR (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- ACSM3 | c.1326+233G>T | Intron (SNP) | VAF 14/157 reads (9%) | catalogued as rs1040301253; called by muse, mutect2
- ADGRE4P | n.1514A>T | RNA (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- AGAP14P | n.986A>T | RNA (SNP) | VAF 60/578 reads (10%) | called by muse, mutect2, varscan2
- B9D1 | chr17:19337736 G>A | 3'Flank (SNP) | VAF 17/187 reads (9%) | catalogued as rs762395732; called by muse, mutect2
- BBS9 | c.2521+18G>T | Intron (SNP) | VAF 59/489 reads (12%) | called by mutect2, varscan2
- C11orf40 | n.48G>T | RNA (SNP) | VAF 39/348 reads (11%) | called by muse, mutect2, varscan2
- CACNB2 | c.213+110386A>G | Intron (SNP) | VAF 22/300 reads (7%) | called by muse, mutect2
- CARD9 | c.*123A>G | 3'UTR (SNP) | VAF 24/670 reads (4%) | called by muse, mutect2
- CHI3L1 | c.1011+27G>A | Intron (SNP) | VAF 67/710 reads (9%) | called by muse, mutect2
- CNMD | c.73-31G>T | Intron (SNP) | VAF 7/38 reads (18%) | called by mutect2, varscan2
- COX7B2 | c.-38C>A | 5'UTR (SNP) | VAF 18/221 reads (8%) | called by muse, mutect2
- CTSC | c.-39C>G | 5'UTR (SNP) | VAF 26/400 reads (7%) | catalogued as rs920101575; called by muse, mutect2
- DYRK2 | c.198+1615G>A | Intron (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- FCHO2 | c.-27C>T | 5'UTR (SNP) | VAF 14/179 reads (8%) | catalogued as rs1462543630; called by muse, mutect2
- FHL1 | chrX:136146897 T>C | 5'Flank (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- GATA4 | c.-65C>T | 5'UTR (SNP) | VAF 28/555 reads (5%) | called by muse, mutect2
- INHBE | chr12:57454976 G>C | 5'Flank (SNP) | VAF 17/182 reads (9%) | called by muse, mutect2, varscan2
- LHX6 | c.*15C>G | 3'UTR (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- LINC01548 | n.343C>T | RNA (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- LINC02207 | n.1769C>A | RNA (SNP) | VAF 28/188 reads (15%) | called by muse, mutect2, varscan2
- LY6E | chr8:143018244 C>T | 5'Flank (SNP) | VAF 46/361 reads (13%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+449G>A | Intron (SNP) | VAF 35/328 reads (11%) | called by muse, mutect2, varscan2
- MIR138-1 | n.39C>G | RNA (SNP) | VAF 20/304 reads (7%) | called by muse, mutect2
- MIR7-3 | chr19:4769324 G>C | 5'Flank (SNP) | VAF 32/311 reads (10%) | called by muse, mutect2, varscan2
- MUC1 | c.59-22A>G | Intron (SNP) | VAF 36/416 reads (9%) | called by muse, mutect2
- ONECUT1 | c.1105+8160G>A | Intron (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- PCDHB6 | chr5:141157370 C>A | 3'Flank (SNP) | VAF 58/1032 reads (6%) | called by muse, mutect2
- PDIA3P1 | n.1426G>C | RNA (SNP) | VAF 55/764 reads (7%) | called by muse, mutect2
- PLAC9 | c.*62C>A | 3'UTR (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- POU5F2 | c.*2660del | 3'UTR (DEL) | VAF 13/201 reads (6%) | called by mutect2, pindel
- PRAME | c.22-1802G>T | Intron (SNP) | VAF 13/253 reads (5%) | called by muse, mutect2
- PSMG4 | c.250+428C>T | Intron (SNP) | VAF 13/111 reads (12%) | catalogued as rs1308462375; called by muse, varscan2
- SIPA1 | c.680-47G>T | Intron (SNP) | VAF 9/167 reads (5%) | called by muse, mutect2
- SNORD114-1 | n.41G>T | RNA (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- STX12 | c.471-157A>G | Intron (SNP) | VAF 13/302 reads (4%) | called by muse, mutect2
- SYTL2 | c.1459+1473C>G | Intron (SNP) | VAF 19/177 reads (11%) | catalogued as rs780866892, COSV100313480; called by muse, mutect2, varscan2
- TLE1 | c.372+28A>G | Intron (SNP) | VAF 15/99 reads (15%) | catalogued as rs1304813293; called by muse, mutect2, varscan2
- TMCO1 | c.*487G>C | 3'UTR (SNP) | VAF 18/312 reads (6%) | called by muse, mutect2
- TMEM135 | c.*774C>G | 3'UTR (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- TYR | c.*3G>T | 3'UTR (SNP) | VAF 62/519 reads (12%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4831G>C | Intron (SNP) | VAF 14/322 reads (4%) | called by muse, mutect2
- ZNF300P1 | n.1450A>G | RNA (SNP) | VAF 15/200 reads (8%) | called by muse, mutect2
